Somatic mutation profile of tumor specimen TCGA-EL-A4KH-01A (aliquot TCGA-EL-A4KH-01A-11D-A257-08) from TCGA case TCGA-EL-A4KH, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 36.3 years (13,275 days).
Specimen TCGA-EL-A4KH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 62b5b2cc-4199-4136-aa5f-b79ec17c2e84.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EL-A4KH-10A (Blood Derived Normal), aliquot TCGA-EL-A4KH-10A-01D-A25A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1cbe05ac-e113-4d63-8599-bf108d8376a7

The open-access MAF lists 4 somatic variants for this specimen: 4 protein-altering or splice-affecting.
By variant classification: Missense Mutation 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CAVIN2 | c.718G>A p.D240N | Missense Mutation (SNP) | VAF 8/208 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1290548199, COSV58423461; called by muse, mutect2
- TAPBP | c.152C>T p.P51L | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.039); catalogued as COSV56466289; called by muse, mutect2, varscan2
- ZNF777 | c.233G>T p.G78V | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.125); catalogued as COSV56096085; called by muse, mutect2, varscan2
